Somatic mutation profile of tumor specimen TCGA-2F-A9KW-01A (aliquot TCGA-2F-A9KW-01A-11D-A38G-08) from TCGA case TCGA-2F-A9KW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.6 years (24,703 days).
Specimen TCGA-2F-A9KW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33bf2dd8-5c21-412f-a4b8-3faa55c036c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2F-A9KW-10A (Blood Derived Normal), aliquot TCGA-2F-A9KW-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11e48e04-7f2e-44cf-9181-802e52378f5d

The open-access MAF lists 120 somatic variants for this specimen: 83 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 34, Nonsense Mutation 4, Frame Shift Del 2, RNA 2, Splice Site 2, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 27/53 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs869025203, CM1514549, COSV59538312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGBL2 | c.554G>C p.C185S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54095655; called by muse, mutect2, varscan2
- ANKS1B | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61377763; called by muse, mutect2, varscan2
- ASXL1 | c.803T>G p.I268S | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60122863; called by muse, mutect2, varscan2
- ATRX | c.5924A>C p.N1975T | Missense Mutation (SNP) | VAF 50/626 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV64883947; called by muse, mutect2
- BCOR | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372238241, COSV60703493, COSV60719287; called by muse, mutect2, varscan2
- C6orf136 | c.615G>C p.W205C (on ENST00000376473 / NM_001109938.3; = p.W71C on NM_145029.4) | Missense Mutation (SNP) | VAF 154/583 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1412919002, COSV53316082; called by muse, mutect2, varscan2
- CAMP | c.397A>G p.K133E (on ENST00000296435; = p.K130E on NM_004345.5) | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV56482350; called by muse, mutect2, varscan2
- CARMIL1 | c.3818C>T p.P1273L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.104); catalogued as rs755139805, COSV61524212; called by muse, mutect2, varscan2
- CCM2 | c.1008C>G p.I336M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs1477653578, COSV51848619, COSV51851549; called by muse, mutect2, varscan2
- CDH15 | c.1302G>C p.Q434H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.884); catalogued as COSV57026415, COSV57027964; called by muse, mutect2, varscan2
- CDK6 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as rs902137115, COSV56008604; called by muse, mutect2, varscan2
- CNOT10 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV59395503; called by muse, mutect2, varscan2
- COG7 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV56153374; called by muse, mutect2, varscan2
- CRNN | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55123993; called by muse, mutect2
- DGKG | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53964205; called by muse, mutect2, varscan2
- DLK1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs749760314, COSV57990669; called by muse, mutect2, varscan2
- DMD | c.6762+2T>A p.X2254_splice | Splice Site (SNP) | VAF 15/79 reads (19%) | catalogued as COSV58955618; called by muse, mutect2, varscan2
- DUOXA2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs1395616761, COSV50994934; called by muse, mutect2, varscan2
- EEF1A1 | c.1289G>C p.R430T | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV58550802, COSV58551057; called by muse, mutect2
- EEPD1 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs1266686829, COSV54197048; called by muse, mutect2, varscan2
- EP300 | c.4527G>T p.W1509C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54328516, COSV54346239; called by muse, mutect2, varscan2
- EPHA7 | c.1562C>G p.A521G | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV65192439; called by muse, mutect2, varscan2
- ERBB3 | c.3800G>A p.R1267Q | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs538526313, COSV57264132, COSV57264164; called by muse, mutect2, varscan2
- FAM47A | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374052739, COSV60496340; called by muse, mutect2, varscan2
- FAT4 | c.5345G>A p.G1782E | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58710089, COSV99060151; called by muse, mutect2, varscan2
- FBXO46 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs771511105, COSV58347804; called by muse, mutect2, varscan2
- FIG4 | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV57791633; called by muse, mutect2, varscan2
- FLAD1 | c.1570G>C p.D524H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV52700154; called by muse, mutect2, varscan2
- FNDC1 | c.5224A>C p.S1742R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51948215; called by muse, mutect2, varscan2
- GBF1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752314787, COSV64143413; called by muse, mutect2, varscan2
- GRIK2 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV59711564, COSV59774939, COSV59776455; called by muse, mutect2, varscan2
- HGS | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs769758521, COSV61270455; called by muse, mutect2, varscan2
- HSPA12B | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs769647913, COSV54766534; called by muse, mutect2, varscan2
- IFI16 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55540431; called by muse, mutect2, varscan2
- KPNB1 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV51600796; called by muse, mutect2, varscan2
- KRT32 | c.529G>C p.A177P | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754145682; called by muse, mutect2, varscan2
- LATS1 | c.2452A>G p.S818G | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53600389; called by muse, mutect2, varscan2
- LBHD1 | c.821G>C p.R274T (on ENST00000431002 / NM_001367940.1; = p.R248T on NM_024099.3) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.426); catalogued as COSV63472716; called by muse, mutect2, varscan2
- LRP10 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759379379, COSV62077894; called by muse, mutect2, varscan2
- LRRC18 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776174712, COSV53285438; called by muse, mutect2, varscan2
- LRRTM4 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV69142566; called by muse, mutect2, varscan2
- MXD1 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.836); catalogued as rs1309684197, COSV52480932; called by muse, varscan2
- MYH4 | c.4142C>T p.T1381M | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs930410014, COSV55126844; called by muse, mutect2, varscan2
- NBEA | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100084690; called by muse, mutect2
- NES | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63960629; called by muse, mutect2, varscan2
- NOM1 | c.1923G>C p.K641N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV51982672; called by muse, mutect2, varscan2
- OR13C8 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1368209555, COSV58612218, COSV58612543; called by muse, mutect2, varscan2
- PEX19 | c.261del p.F87Lfs*5 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as rs781070167, COSV63619474, COSV63620084; called by mutect2, pindel, varscan2
- PIGS | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1337034379, COSV52026667; called by muse, mutect2, varscan2
- PIGZ | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99433980; called by muse, mutect2, varscan2
- PMPCA | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs1325041351, COSV65511101; called by muse, mutect2, varscan2
- PPARGC1A | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53533911; called by muse, mutect2, varscan2
- PPP1R3A | c.1430T>A p.I477N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV52893701, COSV99494448; called by muse, mutect2, varscan2
- RC3H1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51218318; called by muse, mutect2, varscan2
- ROBO4 | c.2795-1G>A p.X932_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as rs1407892374, COSV60628210; called by muse, mutect2, varscan2
- SAMD7 | c.727A>T p.K243* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100157095; called by muse, mutect2, varscan2
- SFSWAP | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55526118; called by muse, mutect2, varscan2
- SLC22A16 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV57934973; called by muse, mutect2, varscan2
- SLC25A35 | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56839179, COSV56840303; called by muse, mutect2, varscan2
- STXBP4 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1313541370, COSV64467543; called by muse, mutect2, varscan2
- TBX3 | c.1339C>G p.R447G (on ENST00000257566 / NM_016569.4; = p.R427G on NM_005996.4) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as COSV99984159; called by muse, mutect2
- TFE3 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1557075317, COSV100252877; called by muse, mutect2, varscan2
- TRRAP | c.8392G>A p.D2798N (on ENST00000359863 / NM_001244580.1; = p.D2780N on NM_003496.3) | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV62851552, COSV62854976; called by muse, mutect2, varscan2
- TTC27 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV58656840; called by muse, mutect2, varscan2
- TUFT1 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100777111, COSV61950656; called by muse, mutect2, varscan2
- UBXN7 | c.731A>G p.Q244R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV56357955; called by muse, mutect2, varscan2
- UGT2B11 | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 51/171 reads (30%) | catalogued as rs202195427; called by muse, mutect2, varscan2
- USP34 | c.1185G>C p.L395F | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101276854, COSV68407077; called by muse, mutect2, varscan2
- YEATS2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV59372720; called by muse, mutect2, varscan2
- YEATS4 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56089911; called by muse, mutect2, varscan2
- ZC3H3 | c.2674T>A p.S892T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.037); catalogued as COSV99368664; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2180G>A p.G727D | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV58744718; called by muse, mutect2, varscan2
- ZNF217 | c.2280G>T p.L760F | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56602764; called by muse, mutect2, varscan2
- ZNF382 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1240336968, COSV53092629; called by muse, mutect2, varscan2
- ZNF599 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV61397535; called by muse, mutect2, varscan2
- ZNF599 | c.1216C>G p.H406D | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV61395834, COSV61397543; called by muse, mutect2, varscan2
- ZNF599 | c.1015T>A p.Y339N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61397548; called by muse, mutect2, varscan2
- GDF2 | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SPATA31D1 | c.4416del p.K1472Nfs*22 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by pindel, varscan2
- TUBGCP6 | c.4224_4225dup p.A1409Gfs*67 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.879dup p.S294Qfs*45 | Frame Shift Ins (INS) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.2631C>T p.T877= | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as COSV52394618; called by muse, mutect2, varscan2
- ARHGAP20 | c.1590C>T p.N530= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs200705132, COSV52811700; called by muse, mutect2, varscan2
- CACNA1S | c.4503C>A p.T1501= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV62943994; called by muse, mutect2, varscan2
- CFL1 | c.336G>A p.K112= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as rs1283584180, COSV100353999, COSV57378441; called by muse, mutect2, varscan2
- ERMAP | c.1341G>A p.P447= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs747086061, COSV60276120; called by muse, mutect2, varscan2
- EVI5 | c.1380G>A p.V460= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV64830354; called by muse, mutect2, varscan2
- FAT4 | c.12423C>T p.V4141= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as rs1259666714, COSV58710100; called by muse, mutect2, varscan2
- GYG1 | c.273G>A p.S91= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs558123408, COSV56051284; called by muse, mutect2, varscan2
- IRS4 | c.678G>C p.A226= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100929762; called by muse, mutect2
- KCNH2 | c.966C>T p.S322= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs200290864, COSV51130495; called by muse, mutect2, varscan2
- LGALS9B | c.849G>A p.Q283= (on ENST00000423676 / NM_001367292.1; = p.Q282= on NM_001042685.2) | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100162934, COSV100163058; called by muse, mutect2, varscan2
- LRRTM4 | c.1119G>T p.L373= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV69142580; called by muse, mutect2, varscan2
- MEGF10 | c.3030G>T p.L1010= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as COSV57256866; called by muse, mutect2, varscan2
- NFASC | c.1449C>T p.N483= (on ENST00000339876 / NM_001378329.1; = p.N494= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as rs202095107, COSV58380941; called by muse, mutect2, varscan2
- NR1H3 | c.651C>T p.L217= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs749883565, COSV68008900; called by muse, mutect2, varscan2
- NWD1 | c.4089C>G p.V1363= | Silent (SNP) | VAF 62/184 reads (34%) | catalogued as COSV60350618; called by muse, mutect2, varscan2
- PCDHA5 | c.1971G>A p.P657= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV65350493; called by muse, mutect2, varscan2
- PDE3A | c.1767C>A p.G589= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs758522081, COSV62983368; called by muse, mutect2, varscan2
- PHF14 | c.2550G>A p.E850= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101301868; called by muse, mutect2
- PLXNB1 | c.6309C>T p.I2103= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99603487; called by muse, mutect2
- PTGES3 | c.348C>T p.D116= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs748522169, COSV56274894; called by muse, mutect2, varscan2
- RIMBP2 | c.2797C>T p.L933= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV55484886; called by muse, mutect2, varscan2
- SCN11A | c.4779C>G p.L1593= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV56578878; called by muse, mutect2, varscan2
- SCN1B | c.423G>A p.K141= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV52895996; called by muse, mutect2, varscan2
- SF3B5 | c.57C>T p.I19= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV62451589; called by muse, mutect2, varscan2
- SLC24A1 | c.1449C>T p.V483= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs749542723, COSV56054294; called by muse, mutect2, varscan2
- SPICE1 | c.1941C>T p.L647= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV55625356; called by muse, mutect2, varscan2
- TNXB | c.9267C>T p.P3089= (on ENST00000647633; = p.P2842= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as COSV64489286; called by muse, mutect2, varscan2
- TTN | c.5730G>A p.V1910= (on ENST00000591111; = p.V1864= on NM_003319.4) | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV60364666; called by muse, mutect2, varscan2
- TYMS | c.828C>T p.F276= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV51895835; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2394T>G p.P798= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV54442881; called by muse, mutect2, varscan2
- VWA3B | c.2166C>A p.I722= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV68247010; called by muse, mutect2, varscan2
- YWHAZ | c.183C>T p.V61= | Silent (SNP) | VAF 54/680 reads (8%) | catalogued as rs1321598530, COSV62053261; called by muse, mutect2
- ZBTB20 | c.1383G>A p.S461= (on ENST00000474710 / NM_001164342.2; = p.S388= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs776479104, COSV61870798; called by muse, mutect2, varscan2
- CRYM-AS1 | n.306G>A | RNA (SNP) | VAF 55/163 reads (34%) | catalogued as rs762586169; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85431G>T | Intron (SNP) | VAF 11/24 reads (46%) | catalogued as rs1302491292, COSV72277526; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1402C>T | RNA (SNP) | VAF 14/32 reads (44%) | catalogued as rs1357255340; called by muse, mutect2, varscan2
